Gene-level copy-number profile of tumor specimen TARGET-10-PATGVX-09A from TARGET case TARGET-10-PATGVX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,668 days).
Specimen TARGET-10-PATGVX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.126038e1-1a1e-586b-a6a6-deea3f2aba5a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATGVX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/fba9ea6e-2313-406a-b324-1cb8c385005e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,394; copy number 2: 56,811; copy number 3: 16; copy number 4: 31; copy number 6: 10.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,300,322, 8 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:130,892,707–131,234,663, 10 genes, copy number 6 (within-gene range 2–6): QRFP, FIBCD1, AL161733.1, LAMC3, AL583807.1, AIF1L, NUP214, RNU6-881P, AL157938.2, AL157938.3.

Autosomal genes at a single copy (total copy number 1): 1,006. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
